Somatic mutation profile of tumor specimen MP2PRT-PATCDD-TMP1-A (aliquot MP2PRT-PATCDD-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATCDD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,026 days).
Specimen MP2PRT-PATCDD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d8e147b-ba79-48c9-8e16-1b82bf41ef01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCDD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCDD-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03e76a51-780e-4d05-8aa8-9f7bd5388f8c

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRX6 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 52/592 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763928591; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 60/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35E2B | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 21/574 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1262692757; called by muse, mutect2
- KIAA2012 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- SPI1 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 88/926 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ABAT | c.387C>T p.P129= | Silent (SNP) | VAF 36/393 reads (9%) | catalogued as rs759203240; called by muse, mutect2
- RP1L1 | c.3297C>T p.S1099= | Silent (SNP) | VAF 212/781 reads (27%) | catalogued as rs574470413; called by muse, mutect2, varscan2
